Somatic mutation profile of tumor specimen 0DAXP6 from CCDI case PBBKBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 3.7 years (1,344 days).
Specimen 0DAXP6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e6266a5-c72e-4e16-9bef-cb5728b05d31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAXP1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88196051-65ec-43d3-a11b-8b696d1aebca

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRG | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 314/690 reads (46%) | catalogued as rs146244921, COSV51647562; called by muse, mutect2, varscan2
- TRIM68 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 42/654 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs187005657; called by muse, mutect2
- MYO15B | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 175/545 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RFX5 | c.1721A>G p.Q574R | Missense Mutation (SNP) | VAF 248/501 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MUC5AC | c.15972C>T p.P5324= | Silent (SNP) | VAF 294/1013 reads (29%) | catalogued as rs756239589; called by muse, mutect2, varscan2
- MR1 | c.604+53T>C | Intron (SNP) | VAF 195/412 reads (47%) | called by muse, mutect2, varscan2
